CCDI case PBBJFF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b629a245-61df-4f99-9f32-49c50042a7f8

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 0.5 years (199 days).

Biospecimens (3 samples)
- Sample 0D9S2Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D9S3D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9S45: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
